Somatic mutation profile of tumor specimen TCGA-AS-3778-01A (aliquot TCGA-AS-3778-01A-01D-0966-08) from TCGA case TCGA-AS-3778, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 35.4 years (12,937 days).
Specimen TCGA-AS-3778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d2705ee-9430-48d3-b56d-f4f9e5dfc5df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AS-3778-10A (Blood Derived Normal), aliquot TCGA-AS-3778-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b9526de-6fc8-48d4-9152-59759fd3a92d

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 33, Silent 14, Frame Shift Del 4, Frame Shift Ins 3, In Frame Del 3, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC3 | c.2005T>G p.Y669D | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs776056911, COSV100700079, COSV62421623; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 153/468 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.142); catalogued as COSV52133464, COSV52155381, COSV52272117; called by muse, mutect2, varscan2
- CYTH2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.774); catalogued as rs1804728, COSV57310342; called by muse, mutect2, varscan2
- DPY19L1 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV60583586; called by muse, mutect2, varscan2
- DYNC1H1 | c.4074+1G>A p.X1358_splice | Splice Site (SNP) | VAF 36/114 reads (32%) | catalogued as COSV64140457, COSV64143860; called by muse, mutect2, varscan2
- GCOM1 | c.332T>C p.L111S | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51095151; called by muse, mutect2, varscan2
- KCNC1 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56397085; called by muse, mutect2, varscan2
- KCNQ2 | c.2501T>C p.I834T (on ENST00000359125 / NM_172107.4; = p.I806T on NM_004518.6) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60551329; called by muse, mutect2, varscan2
- KIF3B | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV65228873; called by muse, mutect2, varscan2
- KRT4 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV53409030; called by muse, mutect2, varscan2
- LMOD2 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV71755626, COSV71755784; called by muse, mutect2, varscan2
- PCDHB7 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV50801583; called by muse, mutect2, varscan2
- PCNX3 | c.3019A>T p.T1007S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63139518; called by muse, mutect2, varscan2
- PKHD1 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61889803; called by muse, mutect2, varscan2
- POLE | c.4461C>G p.I1487M | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV57687029; called by muse, mutect2, varscan2
- PPP1R15B | c.1620A>T p.E540D | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.306); catalogued as COSV65816341; called by muse, mutect2, varscan2
- RAET1G | c.498A>T p.R166S | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV66274843; called by muse, mutect2, varscan2
- RASGRP2 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV62450503; called by muse, mutect2, varscan2
- RNASE9 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58880898; called by muse, mutect2
- RPS29 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs368998907; called by muse, mutect2, varscan2
- RPUSD2 | c.1195G>C p.G399R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59766144; called by muse, mutect2, varscan2
- RUSC1 | c.2576G>T p.R859I (on ENST00000368352 / NM_001105203.2; = p.R390I on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV52741780; called by muse, mutect2, varscan2
- SARS1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 108/582 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.236); catalogued as COSV52322624; called by muse, mutect2, varscan2
- SLC26A11 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.113); catalogued as COSV58340117; called by muse, mutect2, varscan2
- SLC7A10 | c.913-1G>C p.X305_splice | Splice Site (SNP) | VAF 27/85 reads (32%) | catalogued as COSV53506529; called by muse, mutect2, varscan2
- SYNE1 | c.8074T>A p.L2692M (on ENST00000367255 / NM_182961.4; = p.L2699M on NM_033071.3) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV55062465; called by muse, mutect2, varscan2
- TBX18 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV63737679; called by muse, mutect2, varscan2
- THRAP3 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.382); catalogued as COSV63569251; called by muse, mutect2, varscan2
- TLN2 | c.3598A>G p.N1200D | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV60893664; called by muse, mutect2, varscan2
- TRHDE | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53858545; called by muse, mutect2, varscan2
- UTP18 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56584794; called by muse, mutect2, varscan2
- VPS13B | c.11941G>T p.V3981L | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV52554495; called by muse, mutect2, varscan2
- XPC | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV53207061; called by muse, mutect2, varscan2
- XPOT | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 107/310 reads (35%) | catalogued as COSV60347296; called by muse, mutect2, varscan2
- ZBTB41 | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV66359760; called by muse, mutect2, varscan2
- ADGRF4 | c.325del p.S109Lfs*2 | Frame Shift Del (DEL) | VAF 97/375 reads (26%) | called by mutect2, pindel, varscan2
- BCHE | c.907_913del p.N303Hfs*12 | Frame Shift Del (DEL) | VAF 48/172 reads (28%) | called by mutect2, pindel, varscan2
- CLTC | c.912dup p.V305Cfs*6 | Frame Shift Ins (INS) | VAF 84/267 reads (31%) | called by mutect2, pindel, varscan2
- ERICH6 | c.442_450del p.E149_S151del | In Frame Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- L3HYPDH | c.1015_1019dup p.I341Lfs*2 | Frame Shift Ins (INS) | VAF 53/201 reads (26%) | called by mutect2, pindel, varscan2
- NYNRIN | c.4750_4755del p.R1584_S1585del | In Frame Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2680T>G p.F894V (on ENST00000621492; = p.F860V on NM_025248.3) | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STAG1 | c.1910_1911del p.S637Kfs*4 | Frame Shift Del (DEL) | VAF 69/298 reads (23%) | called by mutect2, pindel, varscan2
- SVIL | c.5491_5499del p.L1831_T1833del (on ENST00000355867 / NM_021738.3; = p.L1405_T1407del on NM_003174.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- VHL | c.413dup p.S139Ifs*5 | Frame Shift Ins (INS) | VAF 103/244 reads (42%) | called by mutect2, pindel, varscan2
- ZFYVE27 | c.276_283del p.W92Cfs*25 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- CHRNE | c.789C>T p.F263= | Silent (SNP) | VAF 62/203 reads (31%) | catalogued as COSV53419390; called by muse, mutect2, varscan2
- CTNNA2 | c.970C>A p.R324= | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as COSV63589936, COSV63602878; called by muse, mutect2, varscan2
- DLGAP5 | c.1803A>G p.P601= | Silent (SNP) | VAF 67/211 reads (32%) | catalogued as COSV55964740; called by muse, mutect2, varscan2
- EHD3 | c.990G>A p.E330= | Silent (SNP) | VAF 101/294 reads (34%) | catalogued as COSV59032369; called by muse, mutect2, varscan2
- GUCY2D | c.1131T>A p.A377= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV54697932; called by muse, mutect2, varscan2
- ITPKB | c.2145C>T p.Y715= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs895687672, COSV55266993; called by muse, mutect2, varscan2
- KRT76 | c.1916G>A p.*639= | Silent (SNP) | VAF 94/245 reads (38%) | catalogued as COSV60121513; called by muse, mutect2, varscan2
- MIOS | c.2331C>T p.G777= | Silent (SNP) | VAF 106/337 reads (31%) | catalogued as COSV60770018; called by muse, mutect2, varscan2
- MTAP | c.543A>C p.A181= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV66478240; called by muse, mutect2
- NOS1 | c.2937G>A p.V979= | Silent (SNP) | VAF 29/176 reads (16%) | catalogued as COSV57618559; called by muse, mutect2, varscan2
- PHLPP2 | c.3915T>C p.P1305= | Silent (SNP) | VAF 76/235 reads (32%) | catalogued as COSV62426582; called by muse, mutect2, varscan2
- RAD50 | c.2274T>C p.N758= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV54755826; called by muse, mutect2
- RYR1 | c.12462G>A p.P4154= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs752478710, COSV62106282; called by muse, mutect2, varscan2
- UGT1A10 | c.174C>T p.V58= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs1453192033, COSV60837507; called by muse, mutect2
